Gene-level copy-number profile of tumor specimen TCGA-VT-AB3D-01A from TCGA case TCGA-VT-AB3D, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of upper limb and shoulder; Age at diagnosis: 71.5 years (26,100 days).
Specimen TCGA-VT-AB3D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.051411d6-149b-4a3c-90db-3632fca27ff2.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-VT-AB3D-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f347ca4c-9b79-46df-89e8-bca10acf9e2a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 1,398; copy number 2: 9,391; copy number 3: 22,446; copy number 4: 19,965; copy number 5: 4,595; copy number 6: 1,563; copy number 7: 110; copy number 8: 327; copy number 62: 1; copy number 142: 3; copy number 145: 2; copy number 146: 2; copy number 154: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-VT-AB3D-01A-12D-A416-01): tumor purity 0.29, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:80,245,926–80,974,724, 10 genes: RN7SL869P, AC003988.1, AC004862.1, RN7SL35P, CD36, SNRPBP1, GNAT3, AC073850.1, SEMA3C, AC004972.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 449 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:169,132,531–171,824,959, 65 genes, copy number 7 (broad region; genes not listed).
- chr3:83,924,157–84,051,419, 3 genes, copy number 142: AC092825.1, SRRM1P2, AC117464.1.
- chr3:86,816,740–87,052,738, 3 genes, copy number 62–145: AC108706.1, VGLL3, PPATP1.
- chr4:19,098,199–20,037,972, 8 genes, copy number 7: AC006840.1, LINC02438, RNA5SP157, AC024595.1, AC024230.1, AC110767.1, AC114728.1, AC098862.1.
- chr6:66,710,242–67,625,464, 7 genes, copy number 7–154: AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA.
- chr9:2,621,787–6,331,900, 75 genes, copy number 8 (broad region; genes not listed).
- chr9:6,415,145–6,449,558, 1 gene, copy number 8: AL133480.1.
- chr9:8,314,246–10,612,723, 9 genes, copy number 7–8 (within-gene range 6–8): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1.
- chr13:18,905,419–19,187,618, 15 genes, copy number 7 (within-gene range 3–7): LINC00408, AL355516.1, PHF2P2, LINC00442, USP24P1, GTF2IP3, AL137001.1, AL137001.2, RNA5SP24, CENPIP1, AL139327.2, SMPD4P2, AL139327.3, TUBA3C, AL139327.1.
- chr13:19,422,877–20,091,829, 15 genes, copy number 7 (within-gene range 3–7): TPTE2, CYCSP32, MRPS31P2, ESRRAP1, LINC00350, CASC4P1, MPHOSPH8, PSPC1-AS2, PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2, ZMYM2.
- chr19:6,210,381–8,981,342, 141 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr19:12,825,478–14,942,448, 107 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,398. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
